HCMI case HCM-CSHL-0818-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1bfa0189-6e43-4d76-928c-026673ec775e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1957; Vital status: Alive.

Diagnoses (2)
1. Serous surface papillary carcinoma (the primary disease): ICD-O-3 morphology code: 8461/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Classification of tumor: primary; Age at diagnosis: 62.2 years (22,709 days); AJCC staging edition: 8th; AJCC pathologic T: T3c; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC; FIGO stage: Stage IIIC; Tumor grade: High Grade; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Residual disease: R0; Ovarian specimen status: Ovarian Capsule Intact; Ovarian surface involvement: Present; Peritoneal fluid cytological status: Malignant; Sites of involvement: Peritoneum, NOS / Omentum / Bladder, NOS / Sigmoid colon / Diaphragm / Appendix / Ovary, Right / Fallopian Tube, Left / Pelvic Peritoneum.
   Pathology details: Largest extrapelvic peritoneal focus: Macroscopic (greater than 2cm); Lymph nodes positive: 0; Lymph nodes tested: 0; Tumor largest dimension diameter: 5 cm.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 12 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 33 days; Days to treatment end: 145 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Niraparib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 181 days; Treatment outcome: Treatment Ongoing.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8010/6; ICD-10 code: C78.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Specified parts of peritoneum; Classification of tumor: metastasis; Age at diagnosis: 62.2 years (22,709 days); Peritoneal fluid cytological status: Malignant; Sites of involvement: Ovary, Right / Fallopian Tube, Left / Pelvic Peritoneum / Omentum / Diaphragm / Bladder, NOS / Pelvis / Sigmoid colon / Appendix.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 0; Tumor largest dimension diameter: 5 cm.

Follow-up (5 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Peritoneum, NOS; Days to progression: 0 days; Procedures performed: Colonoscopy.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Specified parts of peritoneum; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Sigmoid colon; Days to progression: 0 days.
- Days to follow up: 496 days (1.4 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 341.

Molecular and laboratory tests
- BRCA1 mutation, nos: Negative.
- BRCA2 mutation, nos: Negative.
- CA-125: 10.
- CA-125: 102.
- CA-125: 68.
- CDKN2A (IHC): Positive.
- ESR1 (IHC): Negative.
- PAX8 (IHC): Positive.
- TP53 (IHC): Overexpressed.
- WT1 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 58.1 kg; Height: 160 cm; BMI: 23.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0818-C56-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0818-C56-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 45; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0818-C56-06A-01-S1-HE: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 40; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 45; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0818-C56-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0818-C56-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
